Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7418, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7418-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS :

(A) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY, THYROIDECTOMY, LEFT LATERAL NECK DISSECTION:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING FOCALLY THYROID CARTILAGE. (SEE COMMENT)

Hyoid bone, no tumor present.

COMMENT: This supplemental report is being issued to give the results of sections submitted for decalcification.

SECTION CODE: A41, A42, representative sections thyroid cartilage; A43, representative section hyoid bone.

DIAGNOSIS

(A) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY, THYROIDECTOMY, LEFT LATERAL NECK DISSECTION:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE LEFT PYRIFORM SINUS (4.0 X 3.5 X 2.0 CM) WITH EXTENSION INTO THE LEFT ARYEPIGLOTTIC FOLD, PREEPIGLOTTIC SPACE AND SUBEPITHELIAL CONNECTIVE TISSUE OF LEFT TRUE VOCAL CORD.

TUMOR EXTENDING FOCALLY TO THE SUBEPITHELIAL CONNECTIVE TISSUE OF THE LEFT INFERIOR LATERAL PYRIFORM SINUS MARGIN OF RESECTION. Tracheal, soft tissue, and other mucosal margins of resection free of tumor.

Left thyroid lobe, no tumor present.

Four perithyroidal lymph nodes, no tumor present.

METASTATIC SQUAMOUS CARCINOMA IN 2 OF 26 CERVICAL LYMPH NODES (1/8 SUBDIGASTRIC, 0/7 MIDJUGULAR, 1/11 LOWER JUGULAR).

COMMENT

Sections of tumor and underlying thyroid cartilage as well as hyoid bone are pending decalcification. A supplemental report will follow when these results are available.

SPECIMEN

(A) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY, THYROIDECTOMY, LEFT LATERAL

[page 2 of 2]
SNOMED CODES
T-55300,M-80703

Source: NCI Genomic Data Commons file ceae7151-81a7-475f-9150-674b3a1688b1 (TCGA-CV-7418.33AFDD4E-9DAB-43C9-B66B-6313225A61E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).